Gene-level copy-number profile of specimen HCM-BROD-0642-C43-85N from HCMI case HCM-BROD-0642-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 54.0 years (19,715 days).
Specimen HCM-BROD-0642-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 45115847-a372-4925-b275-7844ee806d0b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0642-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/449280ba-434a-414f-b171-792e7d968bff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 108; copy number 2: 55,281; copy number 3: 2,955; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:105,337,532–105,349,211, 1 gene: C2orf49.
- chr2:105,363,038–105,378,839, 1 gene (within-gene range 0–2): AC108058.1.
- chr2:190,880,821–190,965,552, 1 gene (within-gene range 0–2): GLS.
- chr2:215,360,440–215,436,073, 1 gene: FN1.
- chr3:134,347,288–134,375,479, 4 genes: AC010207.1, RPL39P5, AMOTL2, MIR6827.
- chr3:157,146,508–157,169,133, 4 genes: CCNL1, Y_RNA, KRT18P34, AC104411.1.
- chr3:185,914,558–185,938,103, 1 gene: TRA2B.
- chr3:194,402,672–194,498,364, 2 genes (within-gene range 0–2): ATP13A3, AC108676.2.
- chr5:138,465,479–138,474,361, 2 genes: EGR1, RPL7P19.
- chr5:139,333,038–139,369,720, 3 genes (within-gene range 0–2): RN7SKP64, PAIP2, AC135457.1.
- chr6:36,442,767–36,491,143, 2 genes (within-gene range 0–2): KCTD20, RN7SL502P.
- chr8:100,913,247–100,958,180, 3 genes: AC027373.1, YWHAZ, RN7SL685P.
- chr9:70,384,597–70,414,624, 1 gene: KLF9.
- chr9:72,351,413–72,365,235, 1 gene: ZFAND5.
- chr11:33,256,672–33,357,023, 1 gene (within-gene range 0–2): HIPK3.
- chr11:65,422,774–65,445,598, 6 genes: NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4.
- chr13:75,620,434–75,859,870, 1 gene (within-gene range 0–2): LMO7.
- chr13:75,688,556–75,883,811, 3 genes (within-gene range 0–1): FAM204CP, LMO7DN, LMO7DN-IT1.
- chr14:64,535,702–64,546,173, 2 genes (within-gene range 0–2): AL049869.3, HSPA2.
- chr14:69,775,416–69,797,241, 1 gene: SLC10A1.
- chr14:75,278,826–75,298,109, 3 genes: FOS, DPPA5P4, LINC01220.
- chr15:63,046,034–63,049,387, 1 gene (within-gene range 0–2): TPM1-AS.
- chr19:11,113,474–11,113,534, 1 gene (within-gene range 0–2): MIR6886.
- chr19:45,467,995–45,497,055, 2 genes (within-gene range 0–2): FOSB, RTN2.
- chr20:35,699,272–35,742,312, 2 genes (within-gene range 0–2): ROMO1, RBM39.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 108. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
